Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AB0H, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AB0H-01A (Primary Tumor).

SPEC #: Status: Obtained: Received:

CLINICAL HISTORY:

ICD 9: 233.1

SPECIMEN/PROCEDURE:

1. CERVIX - BIOPSY

IMPRESSION:

CERVICAL BIOPSY:

Invasive squamous cell carcinoma, large cell, nonkeratinizing.

Dictated by:

Entered:

GROSS DESCRIPTION:

Received, labeled with the patient's name and "one", is a pink to pale-tan tissue fragment that is 0.9 x 0.6 x 0.3 cm. The specimen is entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY (1)/88305

ICD9 Codes:

180.9

Electronically Signed by: _____

ICD 0-3
Carcinoma, squamous cell, large cell
non-keratinizing 8072/3
Site Cervix NOS C53.9
JJS 6/3/14

** END OF REPORT **

Source: NCI Genomic Data Commons file 18c9651d-710f-4113-948a-3a0e648ab884 (TCGA-ZJ-AB0H.4D5AE266-6C48-44FA-A613-4A8BC9160CBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).